Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H3, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H3-01A (Primary Tumor).

[page 1 of 2]
Specimen: A. Lymph node #14, B. Proximal margin (FS),
C. Stomach and lymph node, D. Lymph node #12.

DIAGNOSIS:

A-D) Stomach, total gastrectomy:

- ADVANCED GASTRIC CARCINOMA, SINGLE, MIDDLE THIRD OF STOMACH,
POSTERIOR WALL OF MIDBODY ALONG LESSER CURVATURE,
AGC BORRMANN TYPE 3, TUBULAR ADENOCARCINOMA,
POORLY DIFFERENTIATED, DIFFUSE TYPE, 9 x 8 x 2.5 cm,
with 1) penetration to serosa.

2) no involvement of distal and proximal resection
margins

(distance to margin: distal, 6 cm;
proximal, 3 cm).

3) LYMPHOVASCULAR INVASION: PRESENT.

4) PERINEURAL INVASION: PRESENT.

5) METASTASIS IN 16 OF 36 LYMPH NODES (16/36)

(perigastric LN; 16/35, LN #14; 0/0,
LN #12; 0/1)

(largest metastatic tumor size: 18 mm,
with extranodal extension: 0.5 mm).

ICD-O-3

adenocarcinoma, diffuse type 8145/3

Site: Stomach, Body C16.2

lw 9/27/12

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type per clarification by TSS.

bx discrepancy form attached

lw
10/9/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted to TCGA is inconsistent with the diagnosis selected on the TCGA Case Quality Control Form.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Tubular Adenocarcinoma, Diffuse	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy Between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	According to the original pathology report, this tumor is described as a poorly-differentiated tubular adenocarcinoma. In addendum, we clarified the final diagnosis as an stomach adenocarcinoma, diffuse type	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 4ce84747-84c7-4104-ad2f-df7bb79d4827 (TCGA-HU-A4H3.345715E9-6AC8-4727-96F1-AFBF66E37E43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).